Surgical pathology report (de-identified scan), TCGA case TCGA-24-2261, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2261-01A (Primary Tumor).

[page 1 of 4]
Name:
Address:

MR No.:
Service:
Surgeon:

Surg. Path. No.:
DOB:
Sex/Race:
Location:
Hosp. No.:
Taken/Received:

TCGA-24-2261

DIAGNOSIS

- OVARY, LEFT, EXCISION - ADENOCARCINOMA, POORLY DIFFERENTIATED
(SEE COMMENT)
- EXTENSIVE INVASION INTO SURROUNDING SOFT
TISSUES
- EXTENSIVE LYMPHATIC INVASION IDENTIFIED
- OVARY, RIGHT, EXCISION
- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA
- SALPINX, RIGHT, EXCISION - METASTATIC POORLY DIFFERENTIATED
ADENOCARCINOMA IN LYMPHATICS
- COLON, SIGMOID, PARTIAL EXCISION
- METASTATIC POORLY DIFFERENTIATED
ADENOCARCINOMA IN LYMPHATICS
- STENOSIS, 95%
- SCAR TISSUE AND FOREIGN BODY GRANULOMAS
- DIVERTICULOSIS
- OMENTUM, BIOPSY
- EXTENSIVE METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA

SPECIMEN(S) SUBMITTED

- Part 1: OMENTUM BIOPSY
Part 2: SIGMOID COLON /LEFT OVARY
Part 3: FS1 OMENTUM BIOPSY
Part 4: X1 OMENTUM BIOPSY
Part 5: RIGHT OVARY AND TUBE

HISTORY

The patient is a nulliparous with complex pelvic mass that is contiguous with left ovary and rectosigmoid. Operative procedure: BSO, omentectomy, debulking, rectosigmoid resection with bowel re-anastomosis. An intraoperative non-microscopic consultation was obtained and interpreted as: (1.) Omentum, biopsy - Omentum nearly completely replaced by hard,

[page 2 of 4]
HISTORY (continued)

gray-white metastatic tumor mass with multiple individual smaller tumor nodules. 15.0 x 10.0 x 5.0 cm portion of tumor to [REDACTED] Sigmoid colon and left ovary, excision - Multiple tumor nodules studding bowel serosa and mesentery. In area adjacent to the left ovary tumor surrounds bowel with 95% stenosis of lumen. No mucosal lesion identified. Tumor also involves left ovary. Portions of left ovary, metastasis and colonic mucosa to [REDACTED]

FROZEN

Omentum, biopsy - Poorly differentiated carcinoma [REDACTED]

GROSS

Received are four containers labelled with the patient's name, number and specimen type. The first specimen, labelled "omentum, small piece," is received unfixed and consists of a 1.8 x 1.5 x 0.4 cm piece of firm gray-white tissue. [REDACTED]

The second container, labelled "omentum," is received unfixed. It consists of a 25.0 x 15.0 x 5.0 cm piece of omentum that is nearly completely replaced by matted masses of firm tan-white nodules. [REDACTED]

The third container, labelled "sigmoid colon and left ovary," is received unfixed. It consists of a 25.5 cm length of colon with attached soft tissues. The specimen is opened to reveal an unremarkable mucosa. The soft tissues adjacent to the bowel contain matted masses of firm gray-white tumor nodules. There is an ovary 6.2 cm from one bowel margin, measuring 3.2 x 2.1 x 1.4 cm. Multiple gray-white tumor nodules extend from the ovary and invade surrounding soft tissues. The main tumor mass measures up to 10.0 cm. in greatest dimension. Sections through other portions of the colonic mucosa show multiple diverticuli. No perforations or inflammatory reactions are identified. Labelled: B1 and B2 - colonic margins of resection; B3, B4 - stenotic area of colon; B5, B6 - random sections through pericolic soft tissues; L01 to L03 - sections through left ovary. [REDACTED]

The fourth container, labelled "right ovary and tube," contains an ovary measuring 3.1 x 1.5 x 1.0 cm. The external surfaces are tan-white and lobular. There are several small (<0.2 cm in greatest dimension) firm tan-white nodules studding the surface of the ovary. The fallopian tube measures 6.2 cm in length and up to [REDACTED]

[page 3 of 4]
Name: [REDACTED]

Surg. Path. No.: [REDACTED]

GROSS (continued)

0.7 cm in diameter. The fimbria are thin and delicate. The paraovarian soft tissues contain matted masses of firm gray-white tumor nodules. Labelled: ROT - right tube and ovary; C1 - right paraovarian soft tissue. [REDACTED]

COMMENT

Sections through the left ovary show a poorly differentiated malignant neoplasm composed by a high pleomorphic population of cells with a large, irregular nuclei. Numerous mitotic figures including atypical mitosis are seen. The cells have variable amounts of amphophilic cytoplasm. The majority of the specimen shows the tumor growing in solid sheets. There are a few foci of gland-like configurations, and in one section from the omentum there is a papillary growth pattern. Metastatic deposits of tumor are seen extensively throughout the soft tissues surrounding the sigmoid colon. Tumor is also identified in sections of the right ovary. There is extensive lymphatic invasion in sections from the right adnexa including lymphatics of the fallopian tube. There is also extensive lymphatic invasion throughout the bowel wall. No tumor is identified at the margins of resection of the bowel. In the central portion of the bowel at the site of the stricture, there is scarring in the bowel wall and a foreign body type granuloma is seen.

The main tumor mass is that of a poorly differentiated adenocarcinoma. The histologic appearance and pattern of spread is consistent with a primary in the left ovary. [REDACTED]

(End of Report)

[REDACTED]

Source: NCI Genomic Data Commons file ab9b8346-c39c-4a54-9023-43d0c03d7f47 (TCGA-24-2261.6145AFD6-E7D7-47BC-A659-AC84C3434E86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).